Somatic mutation profile of tumor specimen TCGA-DX-AB2Z-01A (aliquot TCGA-DX-AB2Z-01A-11D-A387-09) from TCGA case TCGA-DX-AB2Z, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DX-AB2Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d47f86a-0221-49dd-ac83-a10564099a52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2Z-10A (Blood Derived Normal), aliquot TCGA-DX-AB2Z-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f1f6aea-9ed3-4ac7-b0c5-4a34c8ec5b00

The open-access MAF lists 72 somatic variants for this specimen: 55 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Nonsense Mutation 3, RNA 2, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPGK | c.1421G>T p.R474L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100295331, COSV61173641; called by muse, mutect2, varscan2
- ARHGAP45 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV57436781; called by muse, mutect2, varscan2
- ATP8B1 | c.1569A>C p.E523D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV99377660; called by muse, mutect2, varscan2
- CACNA1C | c.5023G>A p.A1675T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.198); catalogued as rs773930851, COSV59702061; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CAPN13 | c.1972A>G p.T658A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1326810299, COSV99700776; called by muse, mutect2, varscan2
- CASR | c.2386C>T p.R796C (on ENST00000490131; = p.R873C on NM_000388.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56140889; called by muse, mutect2, varscan2
- CDH7 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.04); catalogued as COSV59890427; called by muse, mutect2, varscan2
- CLUL1 | c.750C>A p.N250K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs1170591705, COSV100621023; called by muse, mutect2, varscan2
- CPVL | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.436); catalogued as COSV55298908, COSV99606260; called by muse, mutect2, varscan2
- DNAH8 | c.3538-1G>A p.X1180_splice | Splice Site (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100546667; called by muse, mutect2, varscan2
- DSEL | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as rs190938093; called by muse, mutect2
- DST | c.16423C>T p.L5475F (on ENST00000361203 / NM_001374722.1; = p.L3063F on NM_015548.5) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99758733; called by muse, mutect2, varscan2
- EPHA6 | c.2224G>A p.G742R (on ENST00000389672 / NM_001080448.3; = p.G134R on NM_173655.4) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101064850; called by muse, mutect2, varscan2
- FAM78B | c.20T>A p.I7N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); catalogued as COSV100597734; called by muse, mutect2, varscan2
- GHSR | c.771C>A p.N257K | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as COSV99576936; called by muse, mutect2, varscan2
- GRIK2 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs1314174085, COSV100028208; called by muse, mutect2
- H1-5 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1291269300, COSV100138019; called by muse, mutect2
- IDH3G | c.330C>A p.N110K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99473349; called by muse, mutect2, varscan2
- KCNA3 | c.1538A>G p.E513G | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100871293; called by muse, mutect2, varscan2
- KIF22 | c.1710G>C p.E570D | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99361362; called by muse, mutect2, varscan2
- KIF22 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99361364; called by muse, mutect2, varscan2
- LAMA3 | c.4009T>A p.C1337S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100557173, COSV100557406; called by muse, mutect2, varscan2
- LTN1 | c.4052C>T p.T1351M | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs759230811, COSV100798118; called by muse, mutect2
- MED13L | c.5498C>G p.S1833C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99929721; called by muse, mutect2, varscan2
- MGAM | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs748580642, COSV71885042; called by muse, mutect2, varscan2
- MKI67 | c.6632C>G p.T2211R | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); catalogued as rs193266380, COSV100896873; called by muse, mutect2, varscan2
- NAIF1 | c.981G>C p.Q327H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1315439201, COSV100895845; called by muse, mutect2, varscan2
- NOTCH1 | c.3926A>T p.N1309I | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV99490417; called by muse, mutect2
- OR2L8 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV100594287; called by muse, mutect2, varscan2
- OR51D1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs138099428; called by muse, mutect2, varscan2
- PIK3AP1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.742); catalogued as COSV100226089; called by muse, mutect2, varscan2
- PRNP | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs181348299, CM054824, COSV101057346; called by mutect2, varscan2
- RBM47 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs773284491, COSV99921314; called by muse, mutect2, varscan2
- RELA | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV100425898; called by muse, mutect2, varscan2
- RGS18 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100817862; called by muse, mutect2, varscan2
- RYR1 | c.15049G>T p.E5017* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100616577; called by muse, mutect2, varscan2
- SALL3 | c.2534A>G p.N845S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV101610008; called by muse, mutect2, varscan2
- SELENOV | c.890A>G p.E297G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59063266, COSV59063663; called by muse, mutect2, varscan2
- SLMAP | c.1400A>G p.Q467R (on ENST00000428312 / NM_001377924.1; = p.Q529R on NM_007159.5) | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV99909008; called by muse, mutect2, varscan2
- SOX12 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.111); catalogued as COSV100705282; called by muse, mutect2
- STXBP4 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1390800232, COSV100894830; called by muse, mutect2, varscan2
- SYNE1 | c.3175A>C p.K1059Q (on ENST00000367255 / NM_182961.4; = p.K1066Q on NM_033071.3) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV99574028; called by muse, mutect2, varscan2
- TDRD7 | c.1932G>T p.E644D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV100795763; called by muse, mutect2
- TECPR1 | c.1999G>A p.V667M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs547498286, COSV101130653; called by muse, mutect2, varscan2
- TMEM131 | c.4012G>A p.A1338T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99489041; called by muse, mutect2, varscan2
- TNFRSF9 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101097333, COSV66348694; called by muse, mutect2, varscan2
- TOR1A | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100693974; called by muse, mutect2, varscan2
- TUBB2B | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 38/268 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99455560; called by muse, mutect2, varscan2
- UBE2I | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.076); catalogued as COSV100171396; called by muse, mutect2, varscan2
- VSX2 | c.627C>A p.C209* | Nonsense Mutation (SNP) | VAF 9/125 reads (7%) | catalogued as COSV100001722; called by muse, mutect2
- ZBED1 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 27/116 reads (23%) | catalogued as COSV100585931; called by muse, mutect2, varscan2
- ZNF225 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99489555; called by muse, mutect2, varscan2
- ZNF710 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs550826482, COSV99184227; called by muse, mutect2, varscan2
- MAGEB6B | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- XPO5 | c.3583G>T p.G1195W | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2
- ADGRE1 | c.162C>T p.Y54= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99165620; called by muse, mutect2, varscan2
- CLEC4F | c.957C>T p.F319= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99713934; called by muse, mutect2
- FAF1 | c.705A>G p.Q235= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs775785819, COSV100875959; called by muse, mutect2, varscan2
- FLT4 | c.3951G>C p.G1317= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV99988287; called by muse, mutect2, varscan2
- FRMPD1 | c.1743G>A p.T581= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs369271811; called by muse, mutect2, varscan2
- KLK4 | c.417G>A p.S139= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs919423328, COSV100133684; called by muse, mutect2, varscan2
- LAMA3 | c.6456G>T p.L2152= (on ENST00000313654 / NM_198129.4; = p.L543= on NM_000227.6) | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99335553; called by muse, mutect2, varscan2
- MYCT1 | c.234C>T p.I78= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100924055; called by muse, mutect2, varscan2
- NRG2 | c.1071C>T p.G357= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs1218781068, COSV99180534; called by muse, mutect2
- PIK3CB | c.753C>T p.S251= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs199909802, COSV100005949; called by muse, mutect2, varscan2
- SLC30A9 | c.216G>A p.Q72= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV100048426; called by muse, mutect2, varscan2
- SPHK2 | c.1440A>G p.A480= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as COSV55336276, COSV99709513; called by muse, mutect2, varscan2
- UNC45B | c.228C>T p.D76= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV99269026; called by muse, mutect2, varscan2
- ZDHHC3 | c.897C>G p.V299= (on ENST00000424952 / NM_001135179.2; = p.V327= on NM_016598.3) | Silent (SNP) | VAF 4/99 reads (4%) | catalogued as rs1218336707, COSV99943613; called by muse, mutect2
- ZFYVE28 | c.897C>T p.D299= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs769423252, COSV52117514; called by muse, mutect2, varscan2
- PKD1L2 | n.4693C>T | RNA (SNP) | VAF 8/67 reads (12%) | catalogued as rs747962383; called by muse, mutect2, varscan2
- SNORD114-21 | n.49C>T | RNA (SNP) | VAF 25/95 reads (26%) | catalogued as rs540952554; called by muse, varscan2
